Gene-level copy-number profile of tumor specimen TCGA-G3-A25W-01A from TCGA case TCGA-G3-A25W, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 79.4 years (29,018 days).
Specimen TCGA-G3-A25W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.8e525a09-3bc3-46aa-98f6-05b3d08d8c86.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G3-A25W-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/184b7bdd-ec05-4a69-927b-93537f2bc97c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 71; copy number 2: 3,374; copy number 4: 41,145; copy number 6: 13,893; copy number 8: 852; copy number 11: 459; copy number 114: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G3-A25W-01A-11D-A16U-01): tumor purity 0.43, ploidy 2.25, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 485 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:241,652,278–242,524,697, 16 genes, copy number 11 (within-gene range 6–11): WDR64, AL365366.1, EXO1, RPL23AP20, BECN2, CFL1P4, MAP1LC3C, TUBB8P6, BX571673.1, PLD5, AL591686.2, RN7SKP12, AL591686.1, AL360271.2, RPL10AP5, AL360271.1.
- chr11:68,941,503–69,775,341, 26 genes, copy number 114: AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4.
- chr17:72,645,949–73,092,712, 1 gene, copy number 11 (within-gene range 6–11): SLC39A11.
- chr17:72,818,836–83,095,122, 442 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 71. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
